Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45P, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45P-01A (Primary Tumor).

[page 1 of 3]
DOB:
Physician:

Sex: F

Received

Pathologist:
Case type: Surgical History

Accession:

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) "BIOPSY OF 25-30.0 CM ESOPHAGEAL MUCOSA":
Squamous mucosa with areas of parakeratosis, no evidence of malignancy.
- (B) "BIOPSY OF RIGHT ORAL TONGUE":
Superficial portion of squamous mucosa with papillomatosis, atypia and marked inflammation.
- (C) "PROXIMAL RIGHT LINGUAL NODE":
Segments of peripheral nerve, no tumor present.
- (D) "RIGHT HEMIGLOSSECTOMY":
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA. (SEE COMMENT)
PERINEURAL INVASION PRESENT.
No vascular/lymphatic invasion present.
Surgical margins, free of tumor.
- (E) "HYPERKERATOSIS, LEFT ALVEOLAR RIDGE":
VERRUCOUS CARCINOMA. (SEE COMMENT)
- (F) "RIGHT INFERIOR MOST JUGULAR LYMPH NODE":
Three lymph nodes, no tumor present.
- (G) "RIGHT NECK DISSECTION":
Nineteen lymph nodes, some of them with follicular hyperplasia, no tumor present (0/2 level 1; 0/4 level 2; 0/6 level 3; 0/0 level 4; 0/7 level 5).
Submandibular gland, no tumor present.
- (H) "LESION ANTERIOR MANDIBULAR GINGIVA":
Hyperkeratotic dysplasia, grade II.

ICD-0-3

Carcinoma, squamous cell, NOS 8070/3
Site: tongue, NOS C02.9
JW
10/1/12

SIGNATURE:

ENTIRE REPORT ELECTRONICALLY SIGNED BY:

COMMENT

The tumor in specimen D (right hemiglossectomy) measures 3.0 cm in greatest dimension and has a depth of invasion of 5.0 mm into the skeletal muscle. In specimen E, left alveolar ridge, the lateral and deep margins are free. However, the anteriormost and posteriormost margins cannot be accurately evaluated in the sections examined.

GROSS DESCRIPTION

(A) BIOPSY OF 25-30 CM ESOPHAGEAL MUCOSA - Specimen consists of a single tan-white soft tissue fragment (0.4 cm diameter).

SECTION CODE: A, entire specimen for frozen section.

*FS/DX: SQUAMOUS MUCOSA WITH AREAS OF PARAKERATOSIS, NO EVIDENCE OF MALIGNANCY.

(B) BIOPSY OF RIGHT ORAL TONGUE - Specimen consists of a single tan soft

[page 2 of 3]
DOB:
Physician:

Sex: F

Received:

Pathologist:

Accession:

Case type: Surgical History

tissue fragment (0.6 x 0.5 x 0.2 cm).

SECTION CODE: B, entire specimen for frozen section.

*FS/DX: SQUAMOUS PAPILLOMA WITH MARKED INFLAMMATION AND ATYPIA, MOST LIKELY RECTIVE.

(C) PROXIMAL RIGHT LINGUAL NODE - Portion of tan-red fibrous tissue (0.3 x 0.3 x 0.2 cm). No discrete lesions are identified grossly. Entirely submitted for frozen section diagnosis in C.

*FS/DX: SEGMENT OF PERIPHERAL NERVE, NO EVIDENCE OF MALIGNANCY.

(D) RIGHT HEMIGLOSSECTOMY - A hemiglossectomy (8.0 x 3.0 x 2.5 cm).

Located 2.0 cm from the anterior margin, 1.7 cm from the posterior margin, 0.7 cm from lateral aspect and 1.4 cm from the medial left superficial margin is an ulcerated focally nodular tan-gray lesion (3.0 x 1.9 cm with a depth of 1.1 cm). The remainder of the specimen is unremarkable.

INK CODE: Blue-deep margin.

SECTION CODE: D1-D11, medial surgical margin submitted in an anterior to posterior fashion, frozen section (D1, D2, D3, D4, D7, D8, D10, D11, superior half, D2, D5, D6, D9, inferior half); D12, representative tumor for frozen section diagnosis; D13-D15, representative sections of the tumor; D16, D17, anteriormost medial surgical margin for permanent section; D18, D19, posteriormost medial margin for permanent section.

*FS/DX: INVASIVE SQUAMOUS CARCINOMA, MARGINS FREE OF TUMOR.

(E) HYPERKERATOSIS LEFT ALVEOLAR RIDGE - A single piece of tan sort tissue (2.9 x 2.6 x 0.2 cm). The mucosal surface is tan-white and raised over most of the surface. On cut section the mucosa has a flat base without an infiltrative margin.

INK CODE: Black-deep.

SECTION CODE: E1-E3, entire specimen for frozen section.

*FS/DX: VERRUCOUS CARCINOMA.

(F) RIGHT INFERIOR MOST JUGULAR LYMPH NODE - Fibroadipose tissue (1.9 x 1.0 x 0.2 cm), containing three tan, rubbery oblong lymph nodes, ranging from 0.3 to 0.5 cm in greatest dimension a piece. Submitted entirely in F. (G)

(G) RIGHT NECK DISSECTION - A loose connective tissue specimen containing multiple lymph nodes and measuring in aggregate 10.2 x 5.5 x 0.6 cm. Lymph nodes from levels 1, 2, 3, 4 and the superficial aspect of level 5 are included.

Two possible level 1 lymph nodes are present measuring 0.5 and 0.7 cm in greatest dimension. Four possible level 2 lymph nodes are present, ranging from 0.3 to 2.1 cm in greatest dimension a piece.

Six possible level 3 lymph nodes are present, ranging from 0.1 to 0.8 cm in greatest dimension a piece.

No level 4 lymph nodes are identified.

Seven possible level 5 lymph nodes are present, ranging from 0.2 to 1.7 cm in greatest dimension a piece. All lymph nodes have a tan-pink rubbery oblong appearance but without gross evidence of tumor.

A tan-pink unremarkable submandibular gland is also present, measuring 3.5 x 2.1 x 1.3 cm.

An ellipse of tan-pink unremarkable skin is also present, measuring 5.0 x 0.5 x 0.2 cm.

SECTION CODE: G1, two possible level 1 lymph nodes; G2-G4, level 2 lymph nodes (G2-G3, one lymph node; G4, three possible lymph nodes); G5-G6, level 3 lymph nodes, three possible lymph nodes per cassette; G7-G9, level 5 lymph nodes (G7, one lymph node; G8, three possible lymph nodes; G9, three possible lymph nodes); G10, random submandibular gland cross section.

(H) LESION ANTERIOR MANDIBULAR GINGIVA - A white-pink rectangular soft tissue

[page 3 of 3]
Sex: F

Received:

Pathologist:

Accession:

Case type: Surgical History

specimen measuring 2.2 x 0.6 x 0.3 cm. The surface is slightly nodular.

INK CODE: Black - surgical margins.

SECTION CODE: H1-H2, entire specimen, cross sections.

SIPTA Discrepancy		

9/9/12

History Case Pathology Report
File under: Pathology

Page 3 of 3
History Case Pathology

Source: NCI Genomic Data Commons file 94ea82f0-b8ca-4e71-a687-c0ba010fdb01 (TCGA-CV-A45P.B1C46313-A9BE-4950-ABE7-EB6E8CF01F5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).